Gene-level copy-number profile of tumor specimen TCGA-MQ-A6BL-01A from TCGA case TCGA-MQ-A6BL, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 78.3 years (28,590 days).
Specimen TCGA-MQ-A6BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.cd3ab64e-a26a-499c-a81b-5d2341fe3cc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MQ-A6BL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1460018c-91cd-4d71-9f92-bb97fd93ed8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 180; copy number 1: 13,162; copy number 2: 43,266; copy number 3: 3,033; copy number 4: 171; copy number 5: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MQ-A6BL-01A-11D-A34B-01): tumor purity 0.29, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 169 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,329,620–30,918,735, 21 genes: LINC01756, AL671862.1, AC092265.1, AL645944.2, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P.
- chr1:46,432,129–48,497,736, 60 genes: FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1.
- chr1:48,552,991–48,776,969, 2 genes: AL391844.1, BEND5.
- chr1:65,248,219–65,641,559, 8 genes: DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1.
- chr1:67,561,073–68,202,987, 10 genes (within-gene range 0–1): AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3.
- chr6:109,165,831–109,382,467, 6 genes (within-gene range 0–1): CCDC162P, AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164.
- chr9:21,638,285–23,438,700, 23 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr18:8,705,661–8,832,778, 1 gene (within-gene range 0–1): MTCL1.
- chr18:8,801,656–10,323,565, 38 genes (within-gene range 0–1): AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450, AP005271.1, AP005209.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:5,013,520–5,113,103, 7 genes, copy number 5: AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474.

Autosomal genes at a single copy (total copy number 1): 10,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
